Somatic mutation profile of tumor specimen ALCH-B0DJ-TTP1-A (aliquot ALCH-B0DJ-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0DJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.8 years (20,373 days).
Specimen ALCH-B0DJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87abf9e8-6c40-4829-93e6-a9b93cb9c71b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0DJ-NB1-A (Blood Derived Normal), aliquot ALCH-B0DJ-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22f81b54-1da1-47a7-abe5-319759e021b1

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 31/473 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2
- TUBGCP2 | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV53304647; called by muse, mutect2
- EED | c.1126-4A>G | Splice Region (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- GABRA1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- GJD2 | c.189C>A p.N63K | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.16); called by muse, mutect2
- NLRC5 | c.1706C>G p.A569G | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2
- PLXNA2 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.275); called by muse, mutect2
- PROSER1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARL2 | c.339+22T>C | Intron (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- TBXAS1 | c.539+12G>A | Intron (SNP) | VAF 11/363 reads (3%) | called by muse, mutect2
- Z96074.1 | n.151+3062C>T | Intron (SNP) | VAF 6/49 reads (12%) | called by muse, varscan2
